TARGET case TARGET-40-NAAHCT — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of limbs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4e2f3a7d-0dc6-558a-a372-447026a97032

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 15 years; Vital status: Dead; Days to death: 178 days.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C40.2; Tissue or organ of origin: Long bones of lower limb and associated joints; Laterality: Left; Classification of tumor: primary; Age at diagnosis: 15.5 years (5,672 days); Year of diagnosis: 2006; Metastasis at diagnosis: Metastasis, NOS; Days to last follow up: 178 days; Sites of involvement: Lung, NOS.
   Treatment given: Protocol identifier: BCM.

Follow-up (1 entry)
- Days to follow up: 178 days; Days to first event: 178 days; First event: Death; Year of follow up: 2006.

Biospecimens (2 samples)
- Sample TARGET-40-NAAHCT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-NAAHCT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Validation_20230329.xlsx (sheet Clinical Data):
- Overall Survival Time in Days: 178
- Protocol: BCM
- Metastasis site: Lung only
- Primary tumor site: Leg/foot
- Specific tumor site: Fibula
- Specific tumor region: Proximal
- Histologic response: Stage 3/4 (91-100 % necrosis)
